Somatic mutation profile of tumor specimen C3N-01091-03 (aliquot CPT0212920006) from CPTAC case C3N-01091, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G3.
Specimen C3N-01091-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36fc6521-74db-41b8-a417-8a00be1c1eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01091-71 (Blood Derived Normal), aliquot CPT0213020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f4e2120-7ad6-4f05-bd24-53575233fbf2

The open-access MAF lists 717 somatic variants for this specimen: 488 protein-altering or splice-affecting, 147 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 393, Silent 147, Intron 39, Frame Shift Del 38, Frame Shift Ins 16, Nonsense Mutation 15, RNA 15, 3'UTR 11, Splice Site 10, In Frame Del 8, Splice Region 7, 5'Flank 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RERE | c.4304A>G p.H1435R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1553154130; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 109/367 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs104893824, CM951283, CM992977, COSV56544751; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT7 | c.883C>T p.R295C (on ENST00000377855 / NM_181864.3; = p.R285C on NM_007274.4) | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs138220668; called by muse, mutect2, varscan2
- ADAMTS7 | c.4324C>T p.R1442W | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs753775871; called by muse, mutect2, varscan2
- ADAMTSL3 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs149710156, COSV99721647; called by muse, mutect2, varscan2
- ADGRE5 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs762532426; called by muse, mutect2, varscan2
- ADPRHL1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs181145159; called by muse, mutect2, varscan2
- AKAP12 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1211053296, COSV53583298; called by muse, mutect2, varscan2
- ALPK3 | c.2304dup p.P769Tfs*8 | Frame Shift Ins (INS) | VAF 55/288 reads (19%) | catalogued as rs1351644582; called by mutect2, varscan2
- ALPK3 | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs201993684, COSV51935973; called by muse, mutect2, varscan2
- ANK3 | c.5548G>T p.A1850S | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.732); catalogued as COSV55054054; called by muse, mutect2
- AP2A2 | c.2039G>A p.G680D | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs1263688174; called by muse, mutect2
- ARHGAP30 | c.2948G>A p.R983Q (on ENST00000368013 / NM_001025598.2; = p.R772Q on NM_181720.3) | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs376108588; called by muse, mutect2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 44/198 reads (22%) | catalogued as rs753865255; called by mutect2, varscan2
- ASXL3 | c.6560G>T p.G2187V | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs1568370381; called by muse, mutect2
- ATP6V0A4 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 97/417 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs894665573, COSV59474270; called by muse, mutect2, varscan2
- ATRNL1 | c.3788G>A p.R1263Q | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs200935343; called by muse, mutect2, varscan2
- B3GAT2 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs1316312636; called by muse, mutect2, varscan2
- BHMT2 | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 51/289 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV99670305; called by muse, mutect2, varscan2
- CACNA1G | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753357544, COSV61720570; called by muse, mutect2, varscan2
- CACNA1H | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1047764685, COSV100673523; called by muse, mutect2
- CAMSAP2 | c.1115T>C p.L372S (on ENST00000236925 / NM_001297707.2; = p.L361S on NM_203459.3) | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1415356000; called by muse, mutect2
- CAPN6 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1378040227; called by muse, mutect2
- CCDC110 | c.1774del p.T592Hfs*5 | Frame Shift Del (DEL) | VAF 45/204 reads (22%) | catalogued as rs368765497; called by mutect2, pindel, varscan2
- CD180 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1054000186; called by muse, mutect2
- CDC14C | c.1046G>A p.R349H (on ENST00000428251; = p.R242H on NM_152627.3) | Missense Mutation (SNP) | VAF 67/365 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs538358544; called by muse, mutect2, varscan2
- CDC42BPB | c.3217dup p.Q1073Pfs*51 | Frame Shift Ins (INS) | VAF 41/155 reads (26%) | catalogued as rs1283001163; called by mutect2, pindel
- CDH23 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs183046743, COSV54941509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP92 | c.1518del p.M507Wfs*74 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as rs1269830199; called by mutect2, pindel, varscan2
- CMIP | c.1558G>A p.A520T (on ENST00000537098 / NM_198390.2; = p.A426T on NM_030629.3) | Missense Mutation (SNP) | VAF 19/513 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1460401544; called by muse, mutect2
- CNOT3 | c.1718G>A p.S573N | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1356524719; called by muse, mutect2
- COL3A1 | c.3706A>G p.T1236A | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58597996; called by muse, mutect2
- COL4A2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs369462083; called by muse, mutect2
- COQ5 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.498); catalogued as rs1351733996; called by muse, mutect2
- COQ8A | c.899T>A p.V300E | Missense Mutation (SNP) | VAF 34/654 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100825570; called by muse, mutect2
- CREB3L2 | c.915+2T>C p.X305_splice | Splice Site (SNP) | VAF 27/340 reads (8%) | catalogued as rs1219249510; called by muse, mutect2
- CRISPLD2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs199608437, COSV52282578; called by muse, mutect2, varscan2
- CSMD2 | c.6505C>T p.R2169W | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774631351, COSV53903749; called by muse, mutect2, varscan2
- CXXC5 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as rs1192784854; called by muse, mutect2, varscan2
- DCAF10 | c.1075del p.S359Hfs*41 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | catalogued as COSV54287878; called by mutect2, pindel, varscan2
- DISP3 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs200276700, COSV99609541; called by muse, mutect2, varscan2
- DNAH10 | c.12772G>A p.D4258N (on ENST00000409039; = p.D4197N on NM_207437.3) | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs373336911; called by muse, mutect2, varscan2
- DNAH17 | c.5863G>A p.G1955R | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764578497, COSV67749570, COSV67759337; called by muse, mutect2, varscan2
- DROSHA | c.2110C>A p.L704M | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.706); catalogued as COSV100757665; called by muse, mutect2, varscan2
- DSCAM | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs749265033, COSV68031900; called by muse, mutect2
- DUOXA1 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146078577, COSV50993446; called by muse, mutect2, varscan2
- EBF3 | c.352A>G p.N118D | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV62471598; called by muse, mutect2
- EIF4A1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs199974690, COSV53441875; called by muse, mutect2, varscan2
- ERVV-1 | c.836del p.P279Lfs*28 | Frame Shift Del (DEL) | VAF 91/579 reads (16%) | catalogued as rs752584775, COSV74083304; called by mutect2, pindel, varscan2
- ESPNL | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 85/548 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140535260; called by muse, varscan2
- FAM71E2 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs976895156; called by muse, mutect2, varscan2
- FBLL1 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 31/566 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs781612353, COSV57924107; called by muse, mutect2
- FHDC1 | c.3175G>A p.G1059S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1319038512; called by muse, mutect2
- FNDC1 | c.4897G>A p.D1633N | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV104395084; called by muse, mutect2, varscan2
- FZD7 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV53811043; called by muse, mutect2
- GAK | c.3274G>A p.G1092S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as rs777675062; called by muse, mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GATA5 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781802523, COSV53346089; ClinVar: uncertain significance; called by muse, mutect2
- GCNT3 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs139466300; called by muse, mutect2, varscan2
- GGT5 | c.1241T>C p.M414T | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as rs759245413; called by muse, mutect2, varscan2
- GGT5 | c.866del p.G289Vfs*11 | Frame Shift Del (DEL) | VAF 39/226 reads (17%) | catalogued as COSV54073059; called by mutect2, pindel, varscan2
- GLI2 | c.2747G>A p.R916H (on ENST00000361492 / NM_001374353.1; = p.R933H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1038692152, CM131867; called by muse, mutect2
- GLUL | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 125/525 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs1394152846, COSV59382343; called by muse, mutect2, varscan2
- GRM3 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs947117751, COSV100862514; called by muse, mutect2
- GSDME | c.314del p.G105Afs*5 | Frame Shift Del (DEL) | VAF 86/404 reads (21%) | catalogued as rs755613828; called by mutect2, pindel, varscan2
- HDAC10 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs760617656; called by muse, mutect2, varscan2
- HDHD5 | c.842G>C p.S281T (on ENST00000336737 / NM_033070.3; = p.S251T on NM_017829.5) | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as COSV50091752; called by muse, mutect2, varscan2
- HEPHL1 | c.1463T>C p.V488A | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753905528; called by muse, mutect2, varscan2
- HOXB1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs138341371; called by muse, mutect2, varscan2
- IFT74 | c.1684+2T>C p.X562_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | catalogued as rs756424645; called by muse, mutect2, varscan2
- ILKAP | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.981); catalogued as COSV54518066; called by muse, mutect2, varscan2
- INO80 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs771801998; called by muse, mutect2
- INSC | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs552439006, COSV65409276; called by muse, mutect2, varscan2
- INTS5 | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV100399736, COSV100399747; called by muse, mutect2, varscan2
- ITGA10 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs150055442; called by muse, mutect2
- ITK | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 67/480 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs201892355; called by muse, mutect2, varscan2
- ITPKC | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1355026070; called by muse, mutect2
- JAK3 | c.2656T>C p.Y886H | Missense Mutation (SNP) | VAF 35/511 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV104438108; called by muse, mutect2
- JPH1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1409446205, COSV60613519; called by muse, mutect2
- KCND3 | c.1898del p.P633Lfs*13 | Frame Shift Del (DEL) | VAF 88/395 reads (22%) | catalogued as COSV56188292; called by mutect2, varscan2
- KCNH7 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.182); catalogued as rs776841666, COSV59812299, COSV59816266; called by muse, mutect2, varscan2
- KHDRBS2 | c.269G>T p.R90M | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55496878; called by muse, mutect2
- KLHL26 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs777114202; called by muse, mutect2, varscan2
- KLK3 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs780090483; called by muse, mutect2, varscan2
- KMT2B | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1379320589; called by muse, mutect2
- KMT2D | c.9329G>A p.R3110H | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs769315900, CD111957, COSV99980398; called by muse, mutect2
- KY | c.198C>T p.H66= | Splice Region (SNP) | VAF 16/118 reads (14%) | catalogued as rs747530241, COSV71016755; called by muse, mutect2, varscan2
- LAMA5 | c.10772C>T p.S3591F | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53364018; called by muse, mutect2
- LARP1 | c.2702G>A p.R901Q (on ENST00000518297 / NM_033551.3; = p.R824Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450704, COSV60427870; called by muse, mutect2, varscan2
- LDB1 | c.257A>G p.D86G (on ENST00000425280 / NM_001321612.2; = p.D50G on NM_003893.5) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63289135; called by muse, mutect2, varscan2
- LLGL2 | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 77/374 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536211924, COSV51365187; called by muse, mutect2, varscan2
- LPCAT4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as rs762591333; called by muse, mutect2, varscan2
- MAP1S | c.1782dup p.S595Qfs*48 | Frame Shift Ins (INS) | VAF 48/250 reads (19%) | catalogued as rs774987060; called by mutect2, varscan2
- MGAT1 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 33/198 reads (17%) | PolyPhen probably damaging (0.981); catalogued as COSV57133238, COSV57135541; called by muse, mutect2, varscan2
- MLH1 | c.2011del p.E671Nfs*112 | Frame Shift Del (DEL) | VAF 74/315 reads (23%) | catalogued as COSV51621371; called by mutect2, pindel, varscan2
- MRPL52 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs372433571; called by muse, mutect2, varscan2
- MTOR | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1031980569, COSV63870844; called by muse, mutect2
- MUC1 | c.3161_3162del p.F1054Sfs*8 (on ENST00000611571 / NM_001371720.1; = p.F65Sfs*8 on NM_002456.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 61/317 reads (19%) | catalogued as rs1369976488; called by mutect2, pindel, varscan2
- MXD3 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 77/288 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs377026834; called by muse, mutect2, varscan2
- MYH10 | c.4397G>A p.R1466H | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs1316635911; called by muse, mutect2, varscan2
- MYO15A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs527582798, COSV52751289; called by muse, mutect2
- MYO18B | c.530del p.P177Lfs*55 | Frame Shift Del (DEL) | VAF 14/157 reads (9%) | catalogued as rs748007891; called by mutect2, pindel
- MYO18B | c.4415G>A p.R1472Q | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771738416, COSV59128718; called by muse, mutect2, varscan2
- N4BP3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1429923433; called by muse, mutect2, varscan2
- NAT8L | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 74/318 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs961920472; called by muse, mutect2, varscan2
- NELL2 | c.2138A>C p.D713A | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as COSV61582837; called by muse, mutect2
- NEU4 | c.292G>A p.V98I (on ENST00000391969 / NM_001167602.3; = p.V110I on NM_080741.4) | Missense Mutation (SNP) | VAF 96/587 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.182); catalogued as rs369482703; called by muse, mutect2, varscan2
- NOTCH1 | c.5585C>T p.P1862L | Missense Mutation (SNP) | VAF 109/458 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs754163232, COSV53060332, COSV99491267; called by muse, mutect2, varscan2
- NTRK2 | c.2206G>A p.V736I (on ENST00000323115 / NM_001369534.1; = p.V752I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/405 reads (21%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs1170229422, COSV52871842; called by muse, mutect2, varscan2
- NUDT13 | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV61968261; called by muse, mutect2
- NUTM1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 104/564 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs1235930540, COSV59218131; called by mutect2, varscan2
- OR2L5 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs773111628, COSV100789470; called by muse, mutect2
- OR5L1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs534141468, COSV61732926; called by muse, mutect2, varscan2
- OR9Q2 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61111266; called by muse, mutect2
- P3R3URF-PIK3R3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 26/311 reads (8%) | PolyPhen benign (0); catalogued as rs996399314; called by muse, mutect2
- PARN | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58367103; called by muse, mutect2
- PAX4 | c.28A>G p.N10D | Missense Mutation (SNP) | VAF 95/526 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490383; called by muse, mutect2, varscan2
- PCDHA13 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 86/1052 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.151); catalogued as COSV56476186; called by muse, mutect2
- PCDHA5 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 39/728 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.801); catalogued as rs147205231, COSV65352077; called by muse, mutect2
- PCDHB5 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs782785858, COSV50686264; called by muse, mutect2
- PCDHB7 | c.2194C>T p.R732* | Nonsense Mutation (SNP) | VAF 86/1382 reads (6%) | catalogued as rs782652788, COSV50754277; called by muse, mutect2
- PCDHGA2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs886859909; called by muse, varscan2
- PCDHGB1 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 148/777 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99536286; called by muse, mutect2, varscan2
- PCK2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 107/342 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs149831874; called by muse, mutect2, varscan2
- PCSK4 | c.1874dup p.R626Afs*71 | Frame Shift Ins (INS) | VAF 37/199 reads (19%) | catalogued as rs1174914612; called by mutect2, pindel, varscan2
- PDZD8 | c.3193A>G p.T1065A | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1387927891; called by muse, mutect2
- PIANP | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57708249, COSV57708254; called by muse, mutect2, varscan2
- PIRT | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as rs868726961, COSV101652681, COSV74119899; called by muse, mutect2, varscan2
- PKD1 | c.11734G>A p.V3912M (on ENST00000262304 / NM_001009944.3; = p.V3911M on NM_000296.4) | Missense Mutation (SNP) | VAF 42/427 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as rs200641313; called by muse, mutect2
- PLEKHA7 | c.2860C>T p.R954W | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264870968, COSV60581200; called by muse, mutect2
- PLEKHA7 | c.2405del p.F802Sfs*21 | Frame Shift Del (DEL) | VAF 38/232 reads (16%) | catalogued as rs1333390805, COSV63043367; called by mutect2, varscan2
- PLEKHG6 | c.2151_2153del p.E718del | In Frame Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs960316144; called by pindel, varscan2
- PLIN5 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1485195347; called by muse, mutect2, varscan2
- PLXND1 | c.4913C>T p.T1638M | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966927392; called by muse, mutect2
- POGLUT1 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs748170466, COSV55156785; called by muse, mutect2, varscan2
- POU4F3 | c.838T>C p.S280P | Missense Mutation (SNP) | VAF 18/649 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047149; called by muse, mutect2
- PPP6R2 | c.2596G>A p.G866S (on ENST00000216061 / NM_001365836.1; = p.G832S on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs367629519; called by muse, mutect2, varscan2
- PREX1 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1380953676; called by muse, mutect2
- PRLHR | c.80A>G p.N27S | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs749784747; called by muse, mutect2, varscan2
- PSG5 | c.898A>G p.T300A | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs752981440; called by muse, mutect2, varscan2
- PSMD2 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774005666; called by muse, mutect2, varscan2
- PTCH2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772212841, COSV64709895, COSV64711757; called by muse, mutect2, varscan2
- PTPN14 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747732994, COSV100872594; called by muse, mutect2, varscan2
- PTPRN2 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1354167350, COSV66104687; called by muse, mutect2
- PTPRN2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 36/121 reads (30%) | catalogued as rs532802114, COSV67026733; called by muse, mutect2, varscan2
- RAD51C | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137947462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP2 | c.6610G>A p.A2204T | Missense Mutation (SNP) | VAF 147/785 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1257076841, COSV51697158; called by muse, mutect2, varscan2
- RASGRF1 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0.169); catalogued as rs773401911; called by muse, mutect2, varscan2
- RFX1 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs749697367; called by muse, mutect2, varscan2
- RIC8A | c.1511G>A p.R504Q (on ENST00000526104 / NM_001286134.1; = p.R510Q on NM_021932.5) | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs141562542; called by muse, mutect2
- RPAIN | c.653T>C p.I218T | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs934304575; called by muse, mutect2
- RPH3A | c.454C>T p.R152C (on ENST00000389385 / NM_001143854.2; = p.R148C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149650638; called by muse, mutect2, varscan2
- RTL1 | c.1324T>C p.F442L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs775184824; called by muse, mutect2, varscan2
- SCLY | c.1282C>T p.R428C (on ENST00000651534; = p.R420C on NM_016510.7) | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550794143, COSV54540675; called by muse, mutect2
- SEMA5A | c.2566A>G p.T856A | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs1272249740; called by muse, mutect2, varscan2
- SENP7 | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV58612801; called by muse, mutect2, varscan2
- SETX | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 23/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56380532; called by muse, mutect2
- SH3BP4 | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs377667134; called by muse, mutect2, varscan2
- SI | c.4005G>A p.W1335* | Nonsense Mutation (SNP) | VAF 40/243 reads (16%) | catalogued as rs372004358; called by muse, mutect2, varscan2
- SLC2A14 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1443485769, COSV61588339; called by muse, mutect2
- SLC4A5 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs779641408; called by muse, mutect2, varscan2
- SMC3 | c.3212_3214del p.G1071del | In Frame Del (DEL) | VAF 26/159 reads (16%) | catalogued as rs773760564; called by mutect2, pindel, varscan2
- SORBS2 | c.2132dup p.N711Kfs*5 | Frame Shift Ins (INS) | VAF 54/236 reads (23%) | catalogued as rs754977280; called by mutect2, varscan2
- SOX14 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 31/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100048352; called by muse, mutect2
- SOX3 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as rs905035128, COSV100983742; called by muse, mutect2, varscan2
- SOX30 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.043); catalogued as rs1311636995; called by muse, mutect2
- SPN | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as rs535306560; called by muse, mutect2
- SRRM4 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 17/616 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs1170712058, COSV57412768; called by muse, mutect2
- STK32C | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1414923464, COSV53840266; called by muse, mutect2
- STX16 | c.160A>G p.M54V (on ENST00000371141 / NM_001001433.3; = p.M33V on NM_003763.6) | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs762816819, COSV56604978; called by muse, mutect2
- SULF2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.012); catalogued as rs1206018127; called by muse, mutect2
- TBC1D22B | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs778955950, COSV65142275, COSV65142509; called by muse, mutect2, varscan2
- TBCD | c.2105G>A p.G702D | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.338); catalogued as rs754528442; called by muse, mutect2
- THSD4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 52/512 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs778584423; called by muse, mutect2
- TLN2 | c.5674A>G p.S1892G | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs1274414668; called by muse, mutect2, varscan2
- TMEM198 | c.467del p.G156Afs*23 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | catalogued as rs1310164939, COSV54719891; called by mutect2, pindel
- TNK2 | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as rs1163181869; called by muse, mutect2
- TPP2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1231094275, COSV65751758; called by muse, mutect2, varscan2
- TSC2 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 26/728 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54758343; called by muse, mutect2
- UCKL1 | c.14del p.P5Rfs*113 | Frame Shift Del (DEL) | VAF 24/148 reads (16%) | catalogued as COSV53877693; called by mutect2, pindel
- UGT2A2 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.453); catalogued as rs200411855; called by muse, mutect2, varscan2
- UROC1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs774371917, COSV104393381; called by muse, mutect2, varscan2
- USP42 | c.2876G>A p.R959H | Missense Mutation (SNP) | VAF 73/357 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1424615668; called by muse, mutect2, varscan2
- VPS13A | c.5075C>T p.T1692I | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1363775292; called by muse, mutect2
- VPS18 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1310656695; called by muse, mutect2, varscan2
- VWA2 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs202058880; called by muse, mutect2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 22/117 reads (19%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR6 | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750346342; called by muse, mutect2, varscan2
- ZCCHC10 | c.475T>G p.S159A (on ENST00000509437 / NM_001300818.3; = p.S137A on NM_017665.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1317667568; called by muse, mutect2, varscan2
- ZFP36 | c.256G>A p.A86T (on ENST00000594442; = p.A80T on NM_003407.5) | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.575); catalogued as COSV50528288; called by muse, mutect2, varscan2
- ZFYVE28 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 40/510 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460795378; called by muse, mutect2
- ZNF208 | c.2816A>G p.H939R | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV68103120; called by muse, mutect2, varscan2
- ZNF208 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.089); catalogued as COSV101236938; called by muse, varscan2
- ZNF223 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV71571793; called by muse, mutect2, varscan2
- ZNF438 | c.2267C>T p.T756I | Missense Mutation (SNP) | VAF 103/448 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs368784672; called by muse, mutect2, varscan2
- ZNF624 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs1413160081, COSV60939507; called by muse, mutect2, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs1264060719; called by mutect2, pindel, varscan2
- ZNF835 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1299839202, COSV73379355; called by muse, mutect2, varscan2
- ZSCAN10 | c.2158G>A p.A720T (on ENST00000252463; = p.A775T on NM_032805.3) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs779961203; called by muse, mutect2, varscan2
- ABCA12 | c.7073T>C p.V2358A (on ENST00000272895 / NM_173076.3; = p.V2040A on NM_015657.3) | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2
- ABCA13 | c.14825A>G p.H4942R | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC098582.1 | c.2980A>T p.I994F | Missense Mutation (SNP) | VAF 23/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACTR3B | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2
- ADAM30 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAMTS16 | c.3325T>C p.C1109R | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- ADAMTS18 | c.667A>G p.N223D | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ADIPOR1 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- AFAP1 | c.1990T>C p.S664P | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFAP1 | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.426); called by muse, mutect2
- AFF2 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- AJUBA | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AKAP17A | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 90/431 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- AL441992.2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AL592490.1 | c.347del p.P116Lfs*11 | Frame Shift Del (DEL) | VAF 36/181 reads (20%) | called by mutect2, pindel, varscan2
- ALDH1L2 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 11/307 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ALPK3 | c.4036T>C p.C1346R | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMOT | c.2427del p.I810Sfs*15 (on ENST00000371959 / NM_001113490.1; = p.I401Sfs*15 on NM_133265.3) | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | called by mutect2, pindel, varscan2
- ANK3 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKZF1 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQP4 | c.376del p.A126Pfs*39 | Frame Shift Del (DEL) | VAF 42/312 reads (13%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.2246+2T>A p.X749_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- ARMC8 | c.1135-3C>T | Splice Region (SNP) | VAF 37/193 reads (19%) | called by muse, mutect2, varscan2
- ASB18 | c.919A>T p.S307C | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- ASIC2 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATAD2B | c.1093_1094del p.F365Qfs*7 | Frame Shift Del (DEL) | VAF 41/216 reads (19%) | called by mutect2, pindel, varscan2
- ATP1A4 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 37/561 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ATP8B1 | c.3653C>T p.A1218V | Missense Mutation (SNP) | VAF 23/546 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ATP8B3 | c.3461A>G p.Y1154C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- BARX2 | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.034); called by muse, mutect2
- BBS9 | c.1550A>T p.D517V | Missense Mutation (SNP) | VAF 26/299 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- BCORL1 | c.3496del p.A1166Lfs*56 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | called by mutect2, pindel
- BRWD3 | c.4301A>G p.Y1434C | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BRWD3 | c.2553-1G>A p.X851_splice | Splice Site (SNP) | VAF 34/93 reads (37%) | called by muse, mutect2, varscan2
- C12orf4 | c.794A>G p.E265G | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2
- C2orf81 | c.1151G>A p.G384D | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C4orf19 | c.85A>G p.N29D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CABIN1 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 126/529 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.3170G>A p.G1057E (on ENST00000350061 / NM_001128840.3; = p.G1077E on NM_000720.4) | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAPN15 | c.760del p.Q254Sfs*33 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- CCDC105 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CCDC136 | c.2692T>C p.C898R | Missense Mutation (SNP) | VAF 92/411 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH8 | c.1656T>A p.D552E | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CELF5 | c.1184_1186del p.E395del | In Frame Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel, varscan2
- CELSR1 | c.6515G>A p.G2172D | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CEP120 | c.1499del p.N500Tfs*27 | Frame Shift Del (DEL) | VAF 29/185 reads (16%) | called by mutect2, pindel, varscan2
- CEP290 | c.6816A>G p.T2272= | Splice Region (SNP) | VAF 57/274 reads (21%) | called by muse, mutect2, varscan2
- CEP89 | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- CES1 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CES5A | c.1514A>G p.D505G (on ENST00000290567 / NM_001143685.2; = p.D455G on NM_145024.3) | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CFAP157 | c.853_855dup p.K285dup | In Frame Ins (INS) | VAF 26/149 reads (17%) | called by mutect2, pindel
- CHD9 | c.2280del p.F760Lfs*16 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | called by mutect2, pindel, varscan2
- CHODL | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- CHST5 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | called by mutect2, varscan2
- CLTC | c.178A>G p.N60D | Missense Mutation (SNP) | VAF 35/413 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- CLUH | c.1715del p.P572Rfs*50 (on ENST00000435359; = p.P610Rfs*50 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/231 reads (20%) | called by mutect2, varscan2
- CMAS | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR1 | c.1520C>T p.P507L (on ENST00000374253 / NM_001297647.2; = p.P500L on NM_006314.3) | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- CNOT3 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COG3 | c.1335del p.Q445Hfs*13 | Frame Shift Del (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- COL6A3 | c.7442C>T p.T2481I | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPB2 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CORO7 | c.2773-5C>T | Splice Region (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- CREB3L2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.9236+2T>C p.X3079_splice | Splice Site (SNP) | VAF 11/393 reads (3%) | called by muse, mutect2
- CUL2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 26/283 reads (9%) | called by muse, mutect2
- CXXC1 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2
- CYB5R1 | c.744del p.D249Ifs*9 | Frame Shift Del (DEL) | VAF 61/422 reads (14%) | called by mutect2, pindel, varscan2
- CYP3A4 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 43/510 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.211); called by muse, mutect2
- DDX5 | c.1619A>G p.Y540C | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); called by muse, mutect2
- DDX59 | c.886A>G p.S296G | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, varscan2
- DEF6 | c.179A>G p.D60G | Missense Mutation (SNP) | VAF 23/291 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- DGAT1 | c.1412T>C p.M471T | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DGKQ | c.2229T>A p.S743R | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- DIAPH1 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 109/615 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.12874A>G p.M4292V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- DNAJC6 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNM2 | c.10C>A p.R4S | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DSP | c.5902T>C p.F1968L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DTWD1 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- DUT | c.473T>G p.I158S (on ENST00000331200 / NM_001025248.2; = p.I70S on NM_001948.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC2H1 | c.9803C>T p.A3268V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EBF3 | c.1249C>A p.R417S (on ENST00000355311 / NM_001375392.1; = p.R408S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- EEA1 | c.1647_1648del p.Y550Cfs*7 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | called by mutect2, pindel, varscan2
- EFNA1 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 18/619 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EFNA2 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EFNB1 | c.956A>G p.K319R | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELP1 | c.2160T>A p.H720Q | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2
- EPB41 | c.606del p.K202Nfs*52 (on ENST00000343067 / NM_001166005.2; = p.K202Nfs*35 on NM_203343.3) | Frame Shift Del (DEL) | VAF 72/386 reads (19%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- ERCC4 | c.2561A>T p.K854I | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- FAM185A | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 93/454 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM221B | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- FAM90A1 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 30/462 reads (6%) | called by muse, mutect2
- FAM98B | c.129A>T p.L43F | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); called by muse, mutect2
- FECH | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.07); called by muse, mutect2
- FITM1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); called by muse, mutect2
- FMNL2 | c.968T>G p.F323C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FN1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 27/626 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); called by muse, mutect2
- FOXP4 | c.1706C>A p.A569E (on ENST00000307972 / NM_001012426.1; = p.A556E on NM_138457.3) | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSIP2 | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FXR2 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 55/264 reads (21%) | called by muse, mutect2, varscan2
- GABRA2 | c.14T>C p.L5S | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRG2 | c.631+7A>G | Splice Region (SNP) | VAF 22/489 reads (4%) | called by muse, mutect2
- GALNTL6 | c.1700_1702del p.K567del | In Frame Del (DEL) | VAF 27/185 reads (15%) | called by pindel, varscan2
- GANAB | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.141); called by muse, mutect2
- GAS8 | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- GJB5 | c.634A>G p.R212G | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2
- GPR151 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR156 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRIN3 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- GRM3 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- GTF2IRD2B | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 42/643 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); called by muse, mutect2
- H3C8 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2
- HIF3A | c.1601C>T p.A534V (on ENST00000377670 / NM_152795.4; = p.A465V on NM_022462.4) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- HOXB3 | c.385A>T p.I129L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2
- HSPG2 | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ICAM3 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 84/338 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- IDI1 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- IDUA | c.970A>G p.K324E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL16 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ING1 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.147); called by muse, mutect2
- INSYN1 | c.873del p.N293Tfs*29 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | called by mutect2, pindel, varscan2
- JAKMIP1 | c.1617G>C p.L539F | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM4C | c.1169A>G p.E390G | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KIAA0930 | c.393C>A p.H131Q (on ENST00000336156 / NM_001009880.2; = p.H136Q on NM_015264.2) | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.255); called by muse, mutect2
- KIF21B | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 42/200 reads (21%) | called by muse, mutect2, varscan2
- KIF26B | c.3622A>G p.T1208A | Missense Mutation (SNP) | VAF 15/387 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- KIRREL1 | c.1786T>C p.Y596H | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.548); called by muse, mutect2
- KIT | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- KLK2 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.005); called by muse, mutect2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 45/200 reads (23%) | called by mutect2, varscan2
- KSR1 | c.1906G>A p.V636M (on ENST00000644974 / NM_001367810.1; = p.V521M on NM_014238.2) | Missense Mutation (SNP) | VAF 40/617 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCLAT1 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGALSL | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LHX5 | c.147_149del p.K49_L50delinsN | In Frame Del (DEL) | VAF 22/119 reads (18%) | called by mutect2, pindel, varscan2
- LMNTD1 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRFN2 | c.557A>T p.D186V | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2
- LRRC40 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LTBR | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LY75-CD302 | c.5117G>A p.S1706N | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- MACF1 | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 17/192 reads (9%) | called by muse, mutect2
- MAG | c.1304dup p.S436Vfs*10 | Frame Shift Ins (INS) | VAF 35/347 reads (10%) | called by mutect2, pindel, varscan2
- MAGI2 | c.1571T>G p.V524G | Missense Mutation (SNP) | VAF 51/522 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- MAMDC4 | c.1494del p.E499Rfs*44 | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- MAP2K7 | c.125-2A>G p.X42_splice | Splice Site (SNP) | VAF 28/126 reads (22%) | called by muse, varscan2
- MAP2K7 | c.204dup p.A69Rfs*23 | Frame Shift Ins (INS) | VAF 16/126 reads (13%) | called by pindel, varscan2
- MED12L | c.761G>A p.W254* | Nonsense Mutation (SNP) | VAF 46/252 reads (18%) | called by muse, mutect2, varscan2
- MEF2C | c.1305C>A p.D435E | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- MEI1 | c.2150C>T p.A717V | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MTMR2 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 77/371 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MUC4 | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 11/241 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); called by muse, mutect2
- MUC5B | c.17165G>A p.G5722D | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH7 | c.4056G>T p.E1352D | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2
- MYH8 | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 9/273 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.297); called by muse, mutect2
- MYO5C | c.1697A>G p.N566S | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYRF | c.1135G>A p.V379M (on ENST00000278836 / NM_001127392.3; = p.V370M on NM_013279.4) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NEB | c.14137G>A p.A4713T | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NEFH | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- NEURL1B | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- NIM1K | c.800G>C p.G267A | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.714); called by muse, mutect2
- NIPA2 | c.698T>A p.I233N | Missense Mutation (SNP) | VAF 19/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NIPSNAP1 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NKD2 | c.546G>T p.K182N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- NLRP3 | c.1453T>C p.S485P | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.222); called by muse, mutect2
- NMRK1 | c.120+2T>C p.X40_splice | Splice Site (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- NTNG1 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OLIG1 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- OOSP2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- OR14I1 | c.406T>C p.S136P | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ORC6 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- PABPC4 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2
- PABPC5 | c.664T>A p.Y222N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PAX1 | c.1487G>A p.S496N | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- PAX4 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 93/520 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDH11Y | c.2851T>A p.Y951N (on ENST00000400457 / NM_032973.2; = p.Y940N on NM_032971.3) | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2
- PCDH18 | c.1353dup p.T452Yfs*6 | Frame Shift Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.1388T>C p.F463S | Missense Mutation (SNP) | VAF 36/1058 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.736); called by muse, mutect2
- PCDHGC3 | c.701T>A p.V234E | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDE3A | c.2365+2T>C p.X789_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- PELO | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.096); called by muse, mutect2
- PGBD1 | c.565dup p.H189Pfs*21 | Frame Shift Ins (INS) | VAF 63/329 reads (19%) | called by mutect2, pindel, varscan2
- PHF1 | c.1471dup p.H491Pfs*19 (on ENST00000374516 / NM_024165.3; = p.T456Hfs*78 on NM_002636.5) | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- PI4KA | c.746_749delinsTA p.G249Vfs*18 | Frame Shift Del (DEL) | VAF 51/237 reads (22%) | called by pindel, varscan2*
- PIGB | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 61/281 reads (22%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PJA2 | c.31+3A>G | Splice Region (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- PLA2G4A | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PNLIPRP1 | c.1165A>G p.I389V | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PPP1R37 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2
- PRDM8 | c.717del p.S240Pfs*61 | Frame Shift Del (DEL) | VAF 52/289 reads (18%) | called by pindel, varscan2
- PRRC2C | c.6727C>T p.P2243S (on ENST00000367742; = p.P2241S on NM_015172.4) | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRSS37 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- PTCH2 | c.2786G>A p.G929E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- RBFOX2 | c.1223C>T p.A408V (on ENST00000438146 / NM_001349995.2; = p.P321S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- RBM8A | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- RFX1 | c.2115T>C p.S705= | Splice Region (SNP) | VAF 42/153 reads (27%) | called by muse, mutect2, varscan2
- RHBDL1 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHOBTB2 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ROBO2 | c.1704G>A p.W568* | Nonsense Mutation (SNP) | VAF 32/501 reads (6%) | called by muse, mutect2
- RSPO1 | c.471dup p.P158Afs*35 | Frame Shift Ins (INS) | VAF 90/475 reads (19%) | called by mutect2, pindel, varscan2
- SAGE1 | c.2431A>G p.N811D | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SCUBE2 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SEC14L5 | c.2069G>A p.S690N | Missense Mutation (SNP) | VAF 11/245 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.101); called by muse, mutect2
- SEPTIN6 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SERINC5 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 8/225 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SERPIND1 | c.42A>G p.I14M | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.081); called by muse, mutect2
- SERTAD2 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- SETBP1 | c.1376A>G p.K459R | Missense Mutation (SNP) | VAF 58/513 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SFMBT2 | c.210del p.Q71Rfs*8 | Frame Shift Del (DEL) | VAF 56/246 reads (23%) | called by mutect2, pindel
- SFSWAP | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SGSM1 | c.2969del p.V990Afs*17 (on ENST00000400359 / NM_001039948.4; = p.V929Afs*17 on NM_133454.3) | Frame Shift Del (DEL) | VAF 57/290 reads (20%) | called by mutect2, pindel, varscan2
- SLC12A5 | c.1334_1348del p.G445_D449del (on ENST00000454036 / NM_001134771.2; = p.G422_D426del on NM_020708.5) | In Frame Del (DEL) | VAF 32/262 reads (12%) | called by mutect2, pindel, varscan2
- SLC4A9 | c.1474G>A p.D492N (on ENST00000507527 / NM_001258428.2; = p.D468N on NM_031467.3) | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SLC9A8 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SMARCAD1 | c.99_101del p.S34del | In Frame Del (DEL) | VAF 48/287 reads (17%) | called by pindel, varscan2
- SMPD4 | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SMTN | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SNPH | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SNX14 | c.1589C>T p.A530V (on ENST00000314673 / NM_001350535.1; = p.A477V on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- SPEN | c.5819A>G p.E1940G | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SREBF1 | c.2291G>A p.C764Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRFBP1 | c.840T>A p.D280E | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- STARD13 | c.3157C>T p.Q1053* (on ENST00000336934 / NM_001243476.3; = p.Q935* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- STAU1 | c.341dup p.R115Efs*25 (on ENST00000371856 / NM_001319135.1; = p.R34Efs*25 on NM_004602.3) | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | called by mutect2, pindel
- STK11 | c.1019A>C p.Y340S | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2
- STRA8 | c.334+2T>C p.X112_splice (on ENST00000275764; = p.X90_splice on NM_182489.2) | Splice Site (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- SUCLG1 | c.755T>G p.I252S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SURF6 | c.562dup p.A188Gfs*15 | Frame Shift Ins (INS) | VAF 66/347 reads (19%) | called by mutect2, pindel, varscan2
- SYNJ2BP | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TANC1 | c.4027T>C p.S1343P | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAS2R7 | c.667A>T p.R223* | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- TBCE | c.171_172del p.Y58Ffs*2 | Frame Shift Del (DEL) | VAF 88/510 reads (17%) | called by pindel, varscan2
- TCN2 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- TECTA | c.1643A>G p.H548R | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.609); called by muse, mutect2
- TENM2 | c.7094A>G p.Y2365C (on ENST00000518659 / NM_001122679.2; = p.Y2126C on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- TENM3 | c.5027C>T p.S1676L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- THBS3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2
- TMEM178B | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.578); called by muse, mutect2
- TMEM30A | c.664A>G p.N222D | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.119); called by muse, mutect2
- TNS2 | c.976A>G p.K326E (on ENST00000314250 / NM_170754.4; = p.K336E on NM_015319.2) | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPO | c.1447A>G p.N483D | Missense Mutation (SNP) | VAF 50/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRANK1 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 77/285 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TRAP1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRGV10 | c.104A>C p.D35A | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.119); called by muse, mutect2
- TRIM31 | c.497G>T p.R166M | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TRIP12 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- TRPM5 | c.2440G>T p.A814S | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TSNAXIP1 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2
- TTC28 | c.2969T>C p.M990T | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2
- TTLL6 | c.121A>G p.R41G | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.93089A>G p.Y31030C (on ENST00000591111; = p.Y23606C on NM_003319.4) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBGCP6 | c.4249G>A p.A1417T | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.315); called by muse, mutect2
- TYW1 | c.897G>C p.E299D | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- UBE2T | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2
- UGP2 | c.442-1G>A p.X148_splice | Splice Site (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- UNC13A | c.2105C>A p.T702N | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- USP21 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 19/575 reads (3%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2
- UTP25 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- VARS1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- VAT1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 163/757 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCAM1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWA8 | c.4241G>A p.S1414N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.1771del p.Y591Mfs*24 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | called by mutect2, pindel, varscan2
- WDR19 | c.3997A>G p.T1333A | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WIPI1 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- WNT9A | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YAF2 | c.480_481dup p.G161Efs*16 | Frame Shift Ins (INS) | VAF 54/266 reads (20%) | called by mutect2, varscan2
- YBX3 | c.320T>C p.I107T | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2
- YEATS2 | c.472A>G p.N158D | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFHX4 | c.909G>C p.M303I | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- ZIC3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF233 | c.346T>G p.L116V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF280A | c.619A>G p.N207D | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- ZNF292 | c.1167T>A p.C389* | Nonsense Mutation (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- ZNF512B | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZNF536 | c.3385T>C p.S1129P | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.132); called by muse, mutect2
- ZNF579 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 54/530 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- ZNF613 | c.142G>A p.G48R (on ENST00000293471 / NM_001031721.4; = p.G12R on NM_024840.4) | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF677 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- ZNF721 | c.1988G>A p.G663D (on ENST00000338977; = p.G675D on NM_133474.4) | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2
- ZNF76 | c.808A>G p.N270D | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF777 | c.1678A>T p.N560Y | Missense Mutation (SNP) | VAF 37/496 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2
- ZNF827 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZSCAN5A | c.1177T>C p.F393L | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZSCAN9 | c.166_183del p.R56_Q61del | In Frame Del (DEL) | VAF 72/327 reads (22%) | called by mutect2, pindel, varscan2
- ZZEF1 | c.5993C>T p.A1998V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- ADAM33 | c.1509C>T p.D503= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as rs745403787, COSV62935639; called by muse, mutect2, varscan2
- ADAMTS16 | c.2826G>A p.T942= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs761762022; called by muse, mutect2
- ADARB2 | c.1020C>T p.F340= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV67236675; called by muse, mutect2, varscan2
- ALMS1 | c.3384A>G p.G1128= | Silent (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2
- ANK1 | c.1449A>G p.T483= | Silent (SNP) | VAF 32/536 reads (6%) | called by muse, mutect2
- ANK2 | c.5427G>A p.A1809= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs768956474; called by muse, mutect2, varscan2
- ANKRD33B | c.561C>T p.N187= | Silent (SNP) | VAF 69/338 reads (20%) | called by muse, mutect2, varscan2
- ANKS1B | c.90C>A p.I30= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- APAF1 | c.3486T>C p.L1162= (on ENST00000551964 / NM_181861.2; = p.L1108= on NM_001160.3) | Silent (SNP) | VAF 77/404 reads (19%) | called by muse, mutect2, varscan2
- BAZ1B | c.124T>C p.L42= | Silent (SNP) | VAF 13/253 reads (5%) | called by muse, mutect2
- C2orf16 | c.2847T>C p.T949= | Silent (SNP) | VAF 35/354 reads (10%) | called by muse, mutect2, varscan2
- CACNA1I | c.543C>T p.R181= | Silent (SNP) | VAF 28/305 reads (9%) | catalogued as rs772153082, COSV60813622; called by muse, mutect2
- CANX | c.1530T>C p.S510= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- CBARP | c.1440C>T p.R480= | Silent (SNP) | VAF 22/280 reads (8%) | catalogued as rs933772218; called by muse, mutect2
- CBX4 | c.1431C>T p.C477= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs750598235, COSV53967365; called by muse, mutect2, varscan2
- CCDC175 | c.2031C>T p.Y677= | Silent (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- CD27 | c.567T>C p.F189= | Silent (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2, varscan2
- CDCA7 | c.408A>G p.L136= (on ENST00000347703 / NM_145810.3; = p.L215= on NM_031942.5) | Silent (SNP) | VAF 17/318 reads (5%) | called by muse, mutect2
- CHST1 | c.978C>T p.S326= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- COL15A1 | c.1164T>C p.S388= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- COL4A4 | c.4494G>A p.G1498= | Silent (SNP) | VAF 36/290 reads (12%) | catalogued as CD095039; called by muse, mutect2, varscan2
- CORO1A | c.360G>A p.L120= | Silent (SNP) | VAF 137/520 reads (26%) | called by muse, mutect2, varscan2
- CORO1A | c.456T>C p.C152= | Silent (SNP) | VAF 52/254 reads (20%) | called by muse, mutect2, varscan2
- CPB2 | c.192G>A p.K64= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV51677695; called by muse, mutect2
- CSPG4 | c.156G>A p.Q52= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- CTC1 | c.334T>C p.L112= | Silent (SNP) | VAF 41/181 reads (23%) | called by muse, mutect2, varscan2
- CTNNA2 | c.966C>T p.C322= | Silent (SNP) | VAF 33/379 reads (9%) | called by muse, mutect2
- DCDC1 | c.4641T>C p.F1547= (on ENST00000597505 / NM_001367979.1; = p.F654= on NM_020869.3) | Silent (SNP) | VAF 27/102 reads (26%) | called by muse, mutect2
- DDC | c.972A>G p.G324= | Silent (SNP) | VAF 124/635 reads (20%) | called by muse, mutect2, varscan2
- DDX49 | c.1389G>A p.G463= | Silent (SNP) | VAF 38/183 reads (21%) | called by muse, mutect2, varscan2
- DST | c.2436T>C p.N812= (on ENST00000361203 / NM_001374722.1; = p.N486= on NM_001723.6) | Silent (SNP) | VAF 29/183 reads (16%) | called by muse, mutect2, varscan2
- EDAR | c.198C>T p.D66= | Silent (SNP) | VAF 89/416 reads (21%) | catalogued as rs752797854; called by muse, mutect2, varscan2
- ERBB4 | c.1281A>G p.V427= | Silent (SNP) | VAF 12/404 reads (3%) | catalogued as rs1346189613; called by muse, mutect2
- EXOSC7 | c.687G>A p.S229= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as rs1157054263, COSV55555815; called by muse, mutect2
- EYA1 | c.1455A>G p.A485= | Silent (SNP) | VAF 36/430 reads (8%) | called by muse, mutect2
- FBLN5 | c.141A>G p.R47= | Silent (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- FOXD4L5 | c.222C>T p.I74= | Silent (SNP) | VAF 42/1058 reads (4%) | catalogued as COSV101073248; called by muse, mutect2
- FOXE3 | c.648G>A p.L216= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- FZD10 | c.1348C>T p.L450= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs1279765500; called by muse, mutect2
- GJA5 | c.300G>A p.V100= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as COSV99605724; called by muse, mutect2, varscan2
- GPD2 | c.1578T>C p.L526= | Silent (SNP) | VAF 49/359 reads (14%) | called by muse, mutect2, varscan2
- GPRIN1 | c.1866G>A p.A622= | Silent (SNP) | VAF 60/364 reads (16%) | catalogued as rs748838039; called by muse, mutect2, varscan2
- GRIN3B | c.2400C>T p.I800= | Silent (SNP) | VAF 66/284 reads (23%) | catalogued as rs1238944353; called by muse, mutect2, varscan2
- GRM4 | c.2622G>A p.T874= | Silent (SNP) | VAF 47/297 reads (16%) | catalogued as rs763694654; called by muse, mutect2, varscan2
- HASPIN | c.1788C>T p.D596= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV53990730; called by muse, mutect2, varscan2
- HMCN2 | c.13524C>T p.D4508= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as rs545955277; called by muse, mutect2, varscan2
- HMGCS2 | c.1488C>T p.D496= | Silent (SNP) | VAF 20/600 reads (3%) | catalogued as rs1189946297; called by muse, mutect2
- HMGXB3 | c.3933C>A p.P1311= (on ENST00000613459; = p.P1065= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/272 reads (14%) | called by muse, mutect2, varscan2
- HNF1A | c.1563T>A p.T521= | Silent (SNP) | VAF 50/722 reads (7%) | called by muse, mutect2
- HOXA9 | c.633C>T p.C211= | Silent (SNP) | VAF 55/267 reads (21%) | called by muse, mutect2, varscan2
- HSPA12A | c.1446C>T p.G482= | Silent (SNP) | VAF 35/138 reads (25%) | catalogued as rs782735093; called by muse, mutect2, varscan2
- IGFN1 | c.144T>C p.F48= | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs1426301048; called by muse, mutect2, varscan2
- ITGA1 | c.2511T>C p.D837= | Silent (SNP) | VAF 40/601 reads (7%) | called by muse, mutect2
- JAK3 | c.1764C>T p.H588= | Silent (SNP) | VAF 75/388 reads (19%) | catalogued as rs201482851, COSV101512985; called by muse, mutect2, varscan2
- JRK | c.939T>C p.S313= | Silent (SNP) | VAF 80/285 reads (28%) | called by muse, mutect2, varscan2
- KALRN | c.2145C>T p.L715= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as rs144625991; called by muse, mutect2, varscan2
- KBTBD7 | c.1641T>C p.I547= | Silent (SNP) | VAF 24/290 reads (8%) | called by muse, mutect2
- KIAA1109 | c.13266A>G p.V4422= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- LAMA5 | c.9123G>A p.V3041= | Silent (SNP) | VAF 77/343 reads (22%) | catalogued as rs368713787; called by muse, mutect2, varscan2
- LRP2 | c.11235T>C p.C3745= | Silent (SNP) | VAF 40/536 reads (7%) | called by muse, mutect2
- LRP2 | c.8745T>C p.G2915= | Silent (SNP) | VAF 46/700 reads (7%) | called by muse, mutect2
- LRP5 | c.4527C>A p.S1509= | Silent (SNP) | VAF 58/243 reads (24%) | called by muse, mutect2, varscan2
- LRP8 | c.510C>T p.H170= | Silent (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- LZTR1 | c.903T>C p.G301= | Silent (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- MACF1 | c.5292G>A p.R1764= | Silent (SNP) | VAF 36/354 reads (10%) | catalogued as rs1216567291; called by muse, mutect2
- MAG | c.576C>T p.D192= | Silent (SNP) | VAF 30/441 reads (7%) | catalogued as COSV62700329; called by muse, mutect2
- MAGEC2 | c.693T>C p.I231= | Silent (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- MAGI2 | c.3894G>A p.K1298= | Silent (SNP) | VAF 70/308 reads (23%) | catalogued as COSV62664011; called by muse, mutect2, varscan2
- MAP1B | c.6255G>A p.V2085= | Silent (SNP) | VAF 51/283 reads (18%) | called by muse, mutect2, varscan2
- MISP | c.1639C>T p.L547= | Silent (SNP) | VAF 74/305 reads (24%) | called by muse, mutect2, varscan2
- MRC2 | c.1056C>T p.S352= | Silent (SNP) | VAF 56/251 reads (22%) | catalogued as rs200470961; called by muse, mutect2, varscan2
- MROH7 | c.2001G>C p.G667= | Silent (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- MUC16 | c.32106T>A p.S10702= | Silent (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- MUC2 | c.1392G>A p.K464= | Silent (SNP) | VAF 72/281 reads (26%) | called by muse, mutect2, varscan2
- MUC4 | c.7461G>A p.S2487= | Silent (SNP) | VAF 120/1572 reads (8%) | catalogued as rs3096347, COSV62202178; called by muse, mutect2
- MYL6 | c.159G>A p.G53= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV52879436; called by muse, mutect2, varscan2
- MYO15A | c.396G>A p.T132= | Silent (SNP) | VAF 109/472 reads (23%) | catalogued as rs1325831346, COSV52759930; called by muse, mutect2, varscan2
- NDRG4 | c.828T>C p.T276= (on ENST00000570248 / NM_001378344.1; = p.T308= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 20/289 reads (7%) | called by muse, mutect2
- NEB | c.4740C>T p.Y1580= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as rs766168868; ClinVar: likely benign; called by muse, mutect2, varscan2
- NIM1K | c.492T>C p.T164= | Silent (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- NKX1-2 | c.705G>A p.A235= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- NOTCH1 | c.1815C>T p.N605= | Silent (SNP) | VAF 101/518 reads (19%) | catalogued as rs781029850; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10A2 | c.498T>C p.C166= | Silent (SNP) | VAF 38/451 reads (8%) | called by muse, mutect2
- OR5K4 | c.348G>A p.A116= | Silent (SNP) | VAF 95/396 reads (24%) | catalogued as rs756311665, COSV100721351, COSV61583344; called by muse, mutect2, varscan2
- OSBPL7 | c.2034C>T p.Y678= | Silent (SNP) | VAF 16/225 reads (7%) | catalogued as COSV50118056; called by muse, mutect2
- PAPPA2 | c.3756G>A p.Q1252= | Silent (SNP) | VAF 9/121 reads (7%) | catalogued as COSV62790190; called by muse, mutect2
- PCDHA9 | c.2124T>A p.S708= | Silent (SNP) | VAF 50/734 reads (7%) | called by muse, mutect2
- PCDHB11 | c.1971G>A p.T657= | Silent (SNP) | VAF 54/866 reads (6%) | catalogued as rs1554285688; called by muse, mutect2
- PCDHB15 | c.1773G>A p.A591= | Silent (SNP) | VAF 40/1025 reads (4%) | catalogued as rs781995329; called by muse, mutect2
- PCDHGB3 | c.300G>A p.S100= | Silent (SNP) | VAF 67/488 reads (14%) | catalogued as COSV53997615; called by muse, mutect2, varscan2
- PDZD4 | c.1443G>A p.P481= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs1557075911; called by muse, mutect2, varscan2
- PGA3 | c.147A>G p.P49= | Silent (SNP) | VAF 26/567 reads (5%) | called by muse, mutect2
- PI15 | c.462C>T p.P154= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as rs779719877; called by muse, mutect2, varscan2
- PI3 | c.256T>C p.L86= | Silent (SNP) | VAF 17/495 reads (3%) | called by muse, mutect2
- PIF1 | c.999C>T p.F333= | Silent (SNP) | VAF 71/263 reads (27%) | catalogued as rs137960587; called by muse, mutect2, varscan2
- PKD1 | c.9036G>A p.T3012= | Silent (SNP) | VAF 154/705 reads (22%) | catalogued as rs190470234; called by muse, mutect2, varscan2
- PLXDC2 | c.507C>T p.G169= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- PLXND1 | c.3375G>A p.P1125= | Silent (SNP) | VAF 59/255 reads (23%) | catalogued as rs777992382; called by muse, mutect2, varscan2
- PNMA8B | c.942C>T p.S314= | Silent (SNP) | VAF 69/319 reads (22%) | called by muse, mutect2, varscan2
- PNPLA6 | c.1767C>T p.G589= (on ENST00000414982 / NM_001166111.2; = p.G541= on NM_006702.5) | Silent (SNP) | VAF 90/486 reads (19%) | catalogued as rs752720134, COSV99653296; called by muse, mutect2, varscan2
- PPP1R1C | c.57G>A p.Q19= | Silent (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- PTPRZ1 | c.1464A>G p.E488= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs1207245353, COSV66429853; called by muse, mutect2, varscan2
- RFPL4AL1 | c.150T>C p.R50= | Silent (SNP) | VAF 34/702 reads (5%) | catalogued as rs1187183863; called by muse, mutect2
- RGS22 | c.1833C>T p.Y611= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs1281124201; called by muse, mutect2, varscan2
- RHOV | c.459A>G p.V153= | Silent (SNP) | VAF 40/230 reads (17%) | called by muse, mutect2, varscan2
- RIMKLA | c.549T>C p.D183= | Silent (SNP) | VAF 29/380 reads (8%) | called by muse, mutect2
- S1PR5 | c.487C>T p.L163= | Silent (SNP) | VAF 84/444 reads (19%) | called by muse, mutect2, varscan2
- SCART1 | c.861G>A p.S287= | Silent (SNP) | VAF 49/194 reads (25%) | catalogued as rs764816021; called by muse, mutect2, varscan2
- SCLT1 | c.918A>G p.T306= | Silent (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- SEMA3A | c.1540T>C p.L514= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- SEMA3C | c.1701T>C p.F567= | Silent (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- SIGLEC7 | c.1167C>T p.D389= | Silent (SNP) | VAF 62/267 reads (23%) | catalogued as rs773848640; called by muse, mutect2, varscan2
- SIMC1 | c.1356G>A p.P452= (on ENST00000443967 / NM_001308196.1; = p.P471= on NM_001308195.2) | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs777072396; called by muse, mutect2, varscan2
- SLC25A27 | c.697T>C p.L233= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- SLC49A3 | c.42C>A p.P14= | Silent (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- SLC4A5 | c.912G>A p.A304= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as rs376049982; called by muse, mutect2, varscan2
- SLC6A13 | c.198G>T p.G66= | Silent (SNP) | VAF 66/335 reads (20%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.328C>A p.R110= | Silent (SNP) | VAF 118/497 reads (24%) | catalogued as COSV101424294; called by muse, mutect2, varscan2
- SMARCA5 | c.1962T>C p.I654= | Silent (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- SMPD2 | c.897G>A p.R299= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57805604; called by muse, mutect2, varscan2
- SPPL2C | c.1530C>T p.L510= | Silent (SNP) | VAF 87/353 reads (25%) | called by muse, mutect2, varscan2
- SSX7 | c.81T>C p.D27= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV99994060; called by muse, mutect2
- SYNE3 | c.1689G>A p.K563= | Silent (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2, varscan2
- TFPI | c.453A>G p.E151= | Silent (SNP) | VAF 15/221 reads (7%) | called by muse, mutect2
- TGIF2 | c.285C>A p.R95= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- TLN1 | c.1431C>T p.S477= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs149633967; called by muse, mutect2, varscan2
- TNR | c.2823A>G p.E941= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- TNRC6C | c.33T>C p.T11= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- TOB1 | c.558G>A p.K186= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as rs112757466; called by muse, mutect2, varscan2
- TOGARAM2 | c.840G>A p.R280= | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- TRIM6-TRIM34 | c.1080G>A p.L360= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- TSHZ2 | c.2694C>T p.H898= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.89301A>G p.P29767= (on ENST00000591111; = p.P22343= on NM_003319.4) | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- UNC13A | c.1842C>T p.H614= | Silent (SNP) | VAF 18/257 reads (7%) | catalogued as rs977471134, COSV99410017; called by muse, mutect2
- UNC13C | c.3783A>G p.G1261= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- USP13 | c.1632C>T p.C544= | Silent (SNP) | VAF 73/334 reads (22%) | called by muse, mutect2, varscan2
- WDR81 | c.4800C>T p.N1600= (on ENST00000409644 / NM_001163809.2; = p.N549= on NM_152348.4) | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as rs753656730; called by muse, mutect2
- WNK2 | c.5439C>T p.D1813= (on ENST00000297954 / NM_001282394.1; = p.D1776= on NM_006648.3) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs753672407; called by muse, mutect2, varscan2
- WRN | c.1881T>C p.V627= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- ZAN | c.177C>T p.D59= | Silent (SNP) | VAF 11/311 reads (4%) | catalogued as rs1201262758, COSV61805517; called by muse, mutect2
- ZBTB22 | c.1728T>G p.P576= | Silent (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- ZC3H4 | c.3372C>T p.R1124= | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as rs200531887, COSV53410485; called by muse, mutect2, varscan2
- ZC3H7B | c.2676C>T p.C892= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs374895467; called by muse, mutect2, varscan2
- ZMYM2 | c.3075A>G p.L1025= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs746335184; called by muse, mutect2, varscan2
- ZNF394 | c.975G>A p.T325= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs112278286; called by muse, mutect2, varscan2
- ZNF430 | c.1347A>T p.I449= | Silent (SNP) | VAF 20/441 reads (5%) | called by muse, mutect2
- ZNF57 | c.1137T>C p.F379= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- AC024940.1 | n.2587C>T | RNA (SNP) | VAF 14/66 reads (21%) | catalogued as rs748997413; called by muse, mutect2
- AC092691.1 | n.383C>T | RNA (SNP) | VAF 64/258 reads (25%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444517 T>C | 5'Flank (SNP) | VAF 12/142 reads (8%) | catalogued as rs1002296405; called by muse, mutect2
- AC107023.1 | chr12:40448192 G>T | 5'Flank (SNP) | VAF 5/28 reads (18%) | catalogued as rs939355162; called by muse, mutect2
- AC134312.1 | n.372G>A | RNA (SNP) | VAF 9/154 reads (6%) | catalogued as rs1488056371; called by muse, mutect2
- ACSL5 | c.-37del | 5'UTR (DEL) | VAF 47/203 reads (23%) | called by mutect2, pindel, varscan2
- ADAR | c.2496+35_2496+37del | Intron (DEL) | VAF 10/125 reads (8%) | catalogued as rs779843196; called by pindel, varscan2*
- ALG12 | c.*416G>A | 3'UTR (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- APLP1 | c.148-20T>C | Intron (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- BAP1 | c.660-11T>G | Intron (SNP) | VAF 128/392 reads (33%) | catalogued as CS134974; called by muse, mutect2, varscan2
- C11orf40 | n.209A>G | RNA (SNP) | VAF 16/229 reads (7%) | catalogued as rs1446452411; called by muse, mutect2
- CD46 | c.901+25T>A | Intron (SNP) | VAF 27/371 reads (7%) | called by muse, mutect2
- CEP290 | c.1825-297A>T | Intron (SNP) | VAF 36/163 reads (22%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2560C>T | 3'UTR (SNP) | VAF 32/380 reads (8%) | catalogued as rs1332007336; called by muse, mutect2
- CHTF18 | chr16:788106 C>T | 5'Flank (SNP) | VAF 11/206 reads (5%) | called by muse, mutect2
- COL18A1 | c.3972+28G>C | Intron (SNP) | VAF 30/296 reads (10%) | catalogued as COSV60592247; called by mutect2, varscan2
- CYP1B1 | c.*32A>T | 3'UTR (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- DOCK7 | c.1801-1546T>C | Intron (SNP) | VAF 13/141 reads (9%) | called by muse, mutect2
- DYRK3 | c.78-704C>A | Intron (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100895719, COSV65605887; called by muse, mutect2, varscan2
- EEF1D | c.-7-3114C>A | Intron (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- F12 | c.1531+35_1531+37del | Intron (DEL) | VAF 61/294 reads (21%) | called by pindel, varscan2
- FAM197Y1 | n.423A>G | RNA (SNP) | VAF 29/303 reads (10%) | called by muse, mutect2
- FCHO2 | c.940-23A>T | Intron (SNP) | VAF 26/156 reads (17%) | catalogued as rs1201699060; called by mutect2, varscan2
- FER1L4 | n.2820T>G | RNA (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- FLT4 | c.2647+18G>A | Intron (SNP) | VAF 60/277 reads (22%) | called by muse, mutect2, varscan2
- GAS8 | c.*764C>T | 3'UTR (SNP) | VAF 14/188 reads (7%) | catalogued as rs938543928; called by muse, mutect2
- GRIK4 | c.907-2385T>C | Intron (SNP) | VAF 42/240 reads (18%) | called by muse, mutect2, varscan2
- HGD | c.282+34T>C | Intron (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- HNRNPA3P1 | n.409A>G | RNA (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- IL17C | c.6+42T>C | Intron (SNP) | VAF 68/365 reads (19%) | catalogued as rs1176321506; called by muse, mutect2, varscan2
- IL6 | c.471+109G>A | Intron (SNP) | VAF 26/109 reads (24%) | catalogued as rs758370297; called by muse, mutect2, varscan2
- KCTD19 | c.-23dup | 5'UTR (INS) | VAF 13/136 reads (10%) | called by mutect2, pindel
- LDHA | c.*246C>A | 3'UTR (SNP) | VAF 89/316 reads (28%) | called by muse, mutect2, varscan2
- LINC02870 | n.304G>A | RNA (SNP) | VAF 69/313 reads (22%) | called by muse, mutect2, varscan2
- LLGL2 | c.*54C>T | 3'UTR (SNP) | VAF 51/253 reads (20%) | catalogued as rs773110264, COSV99389766; called by muse, mutect2, varscan2
- LMO1 | chr11:8268448 T>C | 5'Flank (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- MCF2L | c.170-46241G>A | Intron (SNP) | VAF 89/414 reads (21%) | called by muse, mutect2, varscan2
- MED14 | chrX:40735781 ins T | 5'Flank (INS) | VAF 22/152 reads (14%) | called by mutect2, varscan2
- MIR125B1 | n.52T>C | RNA (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- MIR320D2 | n.45A>G | RNA (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1470104 G>A | 3'Flank (SNP) | VAF 135/588 reads (23%) | catalogued as rs750661279; called by muse, mutect2, varscan2
- NBPF11 | c.-549+2468C>T | Intron (SNP) | VAF 25/497 reads (5%) | catalogued as rs1416146201; called by muse, mutect2
- NDUFA5 | c.66+63T>C | Intron (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- NELL1 | c.1549+55044G>T | Intron (SNP) | VAF 19/239 reads (8%) | catalogued as rs780856922; called by muse, mutect2
- NGRN | chr15:90275198 G>A | 3'Flank (SNP) | VAF 8/116 reads (7%) | catalogued as rs1325633318, COSV58961793; called by muse, mutect2
- NOTCH1 | c.*7C>T | 3'UTR (SNP) | VAF 41/178 reads (23%) | catalogued as rs758237894, COSV53089406; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.360T>C | RNA (SNP) | VAF 17/295 reads (6%) | called by muse, mutect2
- PARGP1 | n.795C>T | RNA (SNP) | VAF 24/852 reads (3%) | called by muse, mutect2
- PARVA | c.716+12C>A | Intron (SNP) | VAF 26/109 reads (24%) | catalogued as rs776600526; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+9T>C | Intron (SNP) | VAF 65/331 reads (20%) | called by muse, mutect2, varscan2
- PITX1 | c.169+791C>T | Intron (SNP) | VAF 62/291 reads (21%) | called by muse, mutect2, varscan2
- PNKD | c.237-16438A>G | Intron (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- PRKAG2 | c.115-20840T>C | Intron (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- PRRT1 | c.*384G>A | 3'UTR (SNP) | VAF 14/231 reads (6%) | catalogued as rs984205202; called by muse, mutect2
- RAB40C | chr16:630007 G>A | 3'Flank (SNP) | VAF 32/306 reads (10%) | catalogued as rs1040912199; called by muse, mutect2, varscan2
- RAMP2 | chr17:42760680 T>C | 5'Flank (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- RAN | c.248-511G>C | Intron (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- RELN | c.6931-38A>G | Intron (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- RFX8 | c.-53+373del | Intron (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- RNF32 | chr7:156640060 T>C | 5'Flank (SNP) | VAF 39/562 reads (7%) | called by muse, mutect2
- RPLP0P2 | n.1119A>G | RNA (SNP) | VAF 16/422 reads (4%) | called by muse, mutect2
- RUFY2 | c.689+142T>C | Intron (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- SCNN1B | c.1152+27C>A | Intron (SNP) | VAF 13/319 reads (4%) | called by muse, mutect2
- SLC22A11 | c.1058+267C>A | Intron (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- SLC6A10P | n.3497A>G | RNA (SNP) | VAF 7/32 reads (22%) | called by mutect2, varscan2
- SMTN | c.1633-1713T>A | Intron (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- SOX10 | c.*26del | 3'UTR (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- SSB | c.*119del | 3'UTR (DEL) | VAF 33/238 reads (14%) | catalogued as rs770808439; called by mutect2, pindel, varscan2
- ST13P4 | n.465C>T | RNA (SNP) | VAF 62/753 reads (8%) | called by muse, mutect2
- STAT3 | c.372+43G>A | Intron (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- STAT4 | c.*52A>G | 3'UTR (SNP) | VAF 14/350 reads (4%) | catalogued as COSV61832895; called by muse, mutect2
- SYCE1 | c.271+30C>T | Intron (SNP) | VAF 62/271 reads (23%) | catalogued as rs1175811666; called by muse, mutect2, varscan2
- SYT14 | chr1:210162766 del T | 3'Flank (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- THUMPD2 | c.1079-33C>T | Intron (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2
- TJP2 | c.-51_-49del | 5'UTR (DEL) | VAF 29/147 reads (20%) | called by mutect2, pindel, varscan2
- TPT1 | c.102+143A>T | Intron (SNP) | VAF 40/177 reads (23%) | called by muse, varscan2
- TUBA1C | c.214-11518C>T | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- TYRP1 | c.-16T>C | 5'UTR (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- WDR43 | c.607-355T>C | Intron (SNP) | VAF 29/174 reads (17%) | catalogued as rs771303776; called by muse, mutect2, varscan2
- XYLT2 | chr17:50362979 A>G | 3'Flank (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ZNF615 | c.-203A>G | 5'UTR (SNP) | VAF 15/163 reads (9%) | catalogued as COSV100943731; called by muse, mutect2
- ZSCAN32 | c.914+209A>T | Intron (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
